Somatic mutation profile of tumor specimen TCGA-D3-A3CF-06A (aliquot TCGA-D3-A3CF-06A-11D-A196-08) from TCGA case TCGA-D3-A3CF, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 61.4 years (22,425 days).
Specimen TCGA-D3-A3CF-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 00203b21-6817-4416-96e5-adef8c4059db.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D3-A3CF-10A (Blood Derived Normal), aliquot TCGA-D3-A3CF-10A-01D-A198-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4e7f12f4-ed6e-4605-ab6f-f7a4506503d2

The open-access MAF lists 32 somatic variants for this specimen: 25 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 22, Silent 7, Nonsense Mutation 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKMY2 | c.608T>G p.L203W | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV61011962; called by muse, mutect2, varscan2
- ASH1L | c.2203G>C p.E735Q | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.029); catalogued as COSV64209278; called by muse, mutect2, varscan2
- ASPM | c.3652C>G p.H1218D | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.247); catalogued as COSV54131980; called by muse, mutect2
- CTNNA3 | c.974G>A p.R325Q | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs773609785, COSV65583084; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH5 | c.11443G>A p.E3815K | Missense Mutation (SNP) | VAF 15/130 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV54232622; called by muse, varscan2
- DNAH5 | c.11391G>T p.Q3797H | Missense Mutation (SNP) | VAF 15/129 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.035); catalogued as COSV54232641; called by muse, varscan2
- EGF | c.1180C>T p.R394* | Nonsense Mutation (SNP) | VAF 9/48 reads (19%) | catalogued as rs369702571; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EZHIP | c.169G>A p.G57S | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as COSV100539677; called by muse, mutect2, varscan2
- FOXD4L1 | c.640C>G p.L214V | Missense Mutation (SNP) | VAF 21/119 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.899); catalogued as COSV52074869; called by muse, varscan2
- GABRD | c.1222C>T p.R408C | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.663); catalogued as rs200430448; ClinVar: uncertain significance; called by mutect2, varscan2
- GFPT2 | c.1824G>T p.Q608H | Missense Mutation (SNP) | VAF 13/234 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.894); catalogued as COSV53809413; called by muse, mutect2
- GPR20 | c.898G>A p.V300I | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.029); catalogued as rs150478338; called by mutect2, varscan2
- HAO2 | c.200A>T p.E67V | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.48); PolyPhen benign (0.1); catalogued as rs748203423, COSV58040175; called by mutect2, varscan2
- ID2 | c.219G>C p.L73F | Missense Mutation (SNP) | VAF 22/166 reads (13%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.993); catalogued as COSV52170360; called by muse, varscan2
- IFIT2 | c.394A>G p.R132G | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.162); catalogued as rs759821795, COSV51079392; called by muse, mutect2, varscan2
- ILF3 | c.836T>A p.L279Q | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as COSV51559028; called by muse, mutect2, varscan2
- KRTAP4-2 | c.292C>G p.P98A | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.056); catalogued as COSV66658673; called by muse, mutect2
- LAMB2 | c.1934C>T p.P645L | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as COSV59734520; called by muse, mutect2, varscan2
- MEGF10 | c.850C>A p.H284N | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV57250974; called by muse, mutect2, varscan2
- NBEA | c.624C>G p.I208M | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.088); catalogued as rs1443098790, COSV59793974; called by muse, mutect2, varscan2
- NSD1 | c.7519G>A p.G2507S | Missense Mutation (SNP) | VAF 18/138 reads (13%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.003); catalogued as COSV61777997; called by muse, mutect2, varscan2
- PCDHA5 | c.2351A>G p.N784S | Missense Mutation (SNP) | VAF 7/99 reads (7%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.003); catalogued as COSV65353382; called by muse, mutect2
- PLEKHA5 | c.3257-1G>C p.X1086_splice | Splice Site (SNP) | VAF 7/28 reads (25%) | catalogued as COSV54703212; called by muse, mutect2
- WDR6 | c.2288C>A p.S763* | Nonsense Mutation (SNP) | VAF 8/30 reads (27%) | catalogued as COSV100556406, COSV58243966, COSV58244167; called by muse, varscan2
- ZNF99 | c.2111C>A p.P704H | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.857); catalogued as COSV101233690, COSV68055964; called by mutect2, varscan2
- BRD3 | c.144G>A p.K48= | Silent (SNP) | VAF 9/71 reads (13%) | catalogued as COSV57704315; called by muse, mutect2, varscan2
- CYBA | c.228G>T p.V76= | Silent (SNP) | VAF 12/41 reads (29%) | catalogued as COSV55368604; called by muse, mutect2, varscan2
- MAPKAPK2 | c.1020G>T p.R340= | Silent (SNP) | VAF 12/72 reads (17%) | catalogued as COSV54316533; called by muse, mutect2, varscan2
- MSANTD4 | c.627A>G p.K209= | Silent (SNP) | VAF 14/62 reads (23%) | catalogued as COSV57286063; called by muse, mutect2, varscan2
- PLOD1 | c.1542C>T p.T514= | Silent (SNP) | VAF 16/99 reads (16%) | catalogued as rs916626462, COSV52146017; called by muse, mutect2, varscan2
- TOM1L1 | c.114C>T p.I38= | Silent (SNP) | VAF 10/78 reads (13%) | catalogued as COSV61947977, COSV61948018, COSV61948488; called by muse, mutect2, varscan2
- ZNF99 | c.1149C>T p.A383= | Silent (SNP) | VAF 7/63 reads (11%) | catalogued as rs1387971102, COSV68055644, COSV68055965; called by muse, mutect2, varscan2
